Somatic mutation profile of tumor specimen ALCH-ABIQ-TTP1-A (aliquot ALCH-ABIQ-TTP1-A-1-0-D-A487-36) from ALCHEMIST case ALCH-ABIQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.5 years (27,945 days).
Specimen ALCH-ABIQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cf6a149-8800-404a-b551-7020e76d0223.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABIQ-NB1-A (Blood Derived Normal), aliquot ALCH-ABIQ-NB1-A-1-0-D-A487-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/589fd620-f58e-4a78-9e1c-d79512f374b2

The open-access MAF lists 49 somatic variants for this specimen: 39 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 7, Splice Site 3, Nonsense Mutation 2, In Frame Del 1, 5'UTR 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-2A>G p.X51_splice | Splice Site (SNP) | VAF 71/414 reads (17%) | hotspot (GDC flag); catalogued as rs1554654224, CS014762, CS127043, COSV58692638, COSV58692823, COSV58707376; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 129/945 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- DYNC2H1 | c.7985G>A p.R2662Q | Missense Mutation (SNP) | VAF 55/374 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs397514635, CM122745; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLEC5A | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 67/375 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.297); catalogued as COSV69396985; called by muse, mutect2, varscan2
- DPYD | c.882C>G p.F294L | Missense Mutation (SNP) | VAF 74/618 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV64597728; called by muse, mutect2, varscan2
- KALRN | c.5143G>A p.V1715M | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.998); catalogued as rs201338676, COSV62561707; called by muse, mutect2, varscan2
- MEFV | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.04); catalogued as rs774360372, COSV99561468; called by muse, mutect2, varscan2
- MTOR | c.2122C>T p.R708W | Missense Mutation (SNP) | VAF 76/610 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63877304; called by muse, mutect2, varscan2
- NLGN4Y | c.971A>T p.K324M | Missense Mutation (SNP) | VAF 179/508 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100196667; called by muse, mutect2, varscan2
- NRXN2 | c.2597C>T p.T866M | Missense Mutation (SNP) | VAF 59/287 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376826316, COSV55453967; called by muse, mutect2, varscan2
- OR2AG2 | c.455C>A p.A152E | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV58455203; called by muse, mutect2, varscan2
- PKD1 | c.7115C>T p.S2372F | Missense Mutation (SNP) | VAF 203/773 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1210916; called by muse, mutect2, varscan2
- TMEM132C | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as rs746015423, COSV101473712; called by muse, mutect2
- AC098582.1 | c.2751_2756del p.Q918_P919del | In Frame Del (DEL) | VAF 44/384 reads (11%) | called by mutect2, pindel
- ADAMTSL3 | c.4348C>G p.P1450A | Missense Mutation (SNP) | VAF 70/574 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- BCAS3 | c.2206A>G p.R736G (on ENST00000390652 / NM_001353144.2; = p.R721G on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- BIVM-ERCC5 | c.2693C>T p.A898V | Missense Mutation (SNP) | VAF 26/846 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); called by muse, mutect2
- CDC42BPA | c.2316A>C p.L772F | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, varscan2
- COMMD2 | c.193T>A p.L65I | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- DLG5 | c.5221C>G p.P1741A | Missense Mutation (SNP) | VAF 48/555 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- DMRTB1 | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 47/332 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DPYD | c.883C>G p.Q295E | Missense Mutation (SNP) | VAF 74/619 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM166A | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAT3 | c.11183A>C p.H3728P | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- IGHG2 | c.658+1G>T p.X220_splice | Splice Site (SNP) | VAF 32/177 reads (18%) | called by muse, mutect2, varscan2
- KDM6A | c.3659T>A p.I1220K | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2
- KIAA1755 | c.2169+1G>A p.X723_splice | Splice Site (SNP) | VAF 32/335 reads (10%) | called by muse, mutect2
- MEX3A | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MSLN | c.1864G>T p.A622S (on ENST00000382862 / NM_013404.4; = p.A614S on NM_005823.6) | Missense Mutation (SNP) | VAF 65/521 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- OR5B2 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- PLEC | c.115A>C p.T39P | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); called by muse, mutect2
- RNF214 | c.1190G>A p.W397* | Nonsense Mutation (SNP) | VAF 73/551 reads (13%) | called by muse, mutect2, varscan2
- SLC6A2 | c.1358C>T p.T453I | Missense Mutation (SNP) | VAF 45/741 reads (6%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.71); called by muse, mutect2
- SORCS1 | c.3316C>A p.L1106M | Missense Mutation (SNP) | VAF 52/448 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCF19 | c.1007G>T p.C336F | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- TRAF6 | c.910G>C p.G304R | Missense Mutation (SNP) | VAF 40/343 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TUBB8B | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TUBB8B | c.219G>T p.M73I | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ZNF536 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | called by muse, mutect2, varscan2
- ATM | c.4593G>A p.Q1531= | Silent (SNP) | VAF 18/444 reads (4%) | called by muse, mutect2
- DPY19L2 | c.1719T>A p.S573= | Silent (SNP) | VAF 44/214 reads (21%) | called by mutect2, varscan2
- ELAPOR1 | c.1242G>T p.G414= | Silent (SNP) | VAF 31/242 reads (13%) | called by muse, mutect2, varscan2
- HUS1 | c.735A>G p.Q245= | Silent (SNP) | VAF 38/331 reads (11%) | called by muse, mutect2, varscan2
- OR5AC2 | c.300C>A p.I100= | Silent (SNP) | VAF 67/501 reads (13%) | called by muse, mutect2, varscan2
- REM2 | c.1020C>A p.L340= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- SPAG1 | c.1719A>C p.G573= | Silent (SNP) | VAF 29/237 reads (12%) | called by muse, mutect2, varscan2
- HSPB1 | c.-4C>T | 5'UTR (SNP) | VAF 112/1154 reads (10%) | catalogued as rs372833436, COSV99949274; ClinVar: not provided / likely benign / benign; called by muse, mutect2
- SBF2 | c.1860+44C>G | Intron (SNP) | VAF 18/102 reads (18%) | called by muse, mutect2, varscan2
- TRAF4 | c.*208A>G | 3'UTR (SNP) | VAF 38/256 reads (15%) | called by muse, mutect2, varscan2
